Somatic mutation profile of tumor specimen ALCH-B3ZZ-TTP1-A (aliquot ALCH-B3ZZ-TTP1-A-1-0-D-A78R-36) from ALCHEMIST case ALCH-B3ZZ, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Carcinoma, NOS; Age at diagnosis: 67.7 years (24,725 days).
Specimen ALCH-B3ZZ-TTP1-A: Sample type: FFPE Scrolls; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 55a87ce3-e34c-47b1-947e-8b7c5cd06581.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B3ZZ-NB1-A (Blood Derived Normal), aliquot ALCH-B3ZZ-NB1-A-1-0-D-A78R-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/07d6c362-a948-4711-b43b-c7435a2f3ec9

The open-access MAF lists 59 somatic variants for this specimen: 33 protein-altering or splice-affecting, 13 silent, 13 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 30, Silent 13, Intron 6, 5'UTR 3, Splice Site 2, RNA 2, Frame Shift Del 1, 3'UTR 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1921A>G p.K641E (on ENST00000288602 / NM_001374244.1; = p.K601E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 148/536 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.345); catalogued as rs121913364, CM092083, COSV56058494; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.818G>T p.R273L | Missense Mutation (SNP) | VAF 126/536 reads (24%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs28934576, CM004342, CM010472, CM920677, COSV52660980, COSV52664805, COSV52676050, COSV52728930; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- AP5Z1 | c.1378G>A p.A460T | Missense Mutation (SNP) | VAF 54/293 reads (18%) | SIFT tolerated (0.34); PolyPhen benign (0.015); catalogued as rs371881628; called by muse, mutect2, varscan2
- COL4A6 | c.4150C>G p.L1384V | Missense Mutation (SNP) | VAF 47/315 reads (15%) | SIFT tolerated (0.48); PolyPhen probably damaging (0.994); catalogued as rs1396799937; called by muse, mutect2, varscan2
- DISP3 | c.2246G>A p.R749Q | Missense Mutation (SNP) | VAF 24/330 reads (7%) | SIFT tolerated (0.39); PolyPhen probably damaging (0.96); catalogued as rs768453877; called by muse, mutect2
- GLRA4 | c.1087G>A p.E363K | Missense Mutation (SNP) | VAF 9/67 reads (13%) | SIFT tolerated (0.06); PolyPhen benign (0.072); catalogued as rs1484393389, COSV60327709; called by muse, mutect2
- KIF26B | c.2143T>A p.C715S | Missense Mutation (SNP) | VAF 53/257 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.838); catalogued as COSV100832085; called by muse, mutect2, varscan2
- NES | c.2173C>G p.L725V | Missense Mutation (SNP) | VAF 53/446 reads (12%) | SIFT tolerated (0.21); PolyPhen benign (0.091); catalogued as rs1349438187; called by muse, mutect2, varscan2
- OR10R2 | c.175C>G p.L59V | Missense Mutation (SNP) | VAF 42/297 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.847); catalogued as COSV63768721; called by muse, mutect2, varscan2
- RAG1 | c.455C>A p.P152Q | Missense Mutation (SNP) | VAF 22/262 reads (8%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.998); catalogued as COSV55023805; called by muse, mutect2
- SLC26A4 | c.262G>A p.V88I | Missense Mutation (SNP) | VAF 52/678 reads (8%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as rs779745819, CM1111378, COSV55916347; called by muse, mutect2
- ZDHHC1 | c.958C>T p.H320Y | Missense Mutation (SNP) | VAF 47/294 reads (16%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as rs147550802; called by muse, mutect2, varscan2
- ZNF672 | c.1195G>A p.E399K | Missense Mutation (SNP) | VAF 22/240 reads (9%) | SIFT deleterious (0.03); PolyPhen benign (0.092); catalogued as COSV60637378; called by muse, mutect2
- APC | c.4436_4452del p.V1479Gfs*2 | Frame Shift Del (DEL) | VAF 47/144 reads (33%) | called by mutect2, pindel, varscan2
- CCN2 | c.441C>A p.D147E | Missense Mutation (SNP) | VAF 38/458 reads (8%) | SIFT tolerated (0.2); PolyPhen benign (0.12); called by muse, mutect2
- CIT | c.5933G>A p.R1978Q | Missense Mutation (SNP) | VAF 8/75 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.968); called by muse, mutect2
- CLEC9A | c.11A>G p.E4G | Missense Mutation (SNP) | VAF 10/119 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.638); called by muse, mutect2
- EPHA8 | c.532A>C p.K178Q | Missense Mutation (SNP) | VAF 75/216 reads (35%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.883); called by muse, mutect2, varscan2
- EPHB6 | c.1456C>T p.H486Y | Missense Mutation (SNP) | VAF 32/668 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.015); called by muse, mutect2
- GRM1 | c.1570T>C p.C524R | Missense Mutation (SNP) | VAF 54/499 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- HSPE1-MOB4 | c.32C>T p.P11L | Missense Mutation (SNP) | VAF 66/247 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.96); called by muse, mutect2, varscan2
- MCF2 | c.573-2A>T p.X191_splice | Splice Site (SNP) | VAF 13/35 reads (37%) | called by muse, mutect2, varscan2
- NES | c.4654G>A p.G1552R | Missense Mutation (SNP) | VAF 55/116 reads (47%) | SIFT tolerated (0.28); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- OBSCN | c.10855C>A p.L3619I | Missense Mutation (SNP) | VAF 84/523 reads (16%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.8); called by muse, mutect2, varscan2
- RFC3 | c.280G>A p.E94K | Missense Mutation (SNP) | VAF 31/160 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- RPAP1 | c.3160A>G p.S1054G | Missense Mutation (SNP) | VAF 5/67 reads (7%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.541); called by muse, mutect2
- RSF1 | c.1697G>A p.G566D | Missense Mutation (SNP) | VAF 14/164 reads (9%) | SIFT tolerated, low confidence (0.6); PolyPhen benign (0.012); called by muse, mutect2
- SLC12A5 | c.1972C>A p.R658S (on ENST00000454036 / NM_001134771.2; = p.R635S on NM_020708.5) | Missense Mutation (SNP) | VAF 19/102 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.142); called by muse, mutect2, varscan2
- SMC1B | c.1361A>C p.Q454P | Missense Mutation (SNP) | VAF 9/144 reads (6%) | SIFT deleterious (0.05); PolyPhen benign (0.012); called by muse, mutect2
- TAF7L | c.798G>C p.K266N | Missense Mutation (SNP) | VAF 16/229 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.867); called by muse, mutect2
- TREML1 | c.377-1G>A p.X126_splice | Splice Site (SNP) | VAF 22/314 reads (7%) | called by muse, mutect2
- TUBA8 | c.109G>T p.D37Y | Missense Mutation (SNP) | VAF 21/672 reads (3%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.003); called by muse, mutect2
- WDR64 | c.771A>T p.K257N | Missense Mutation (SNP) | VAF 39/188 reads (21%) | SIFT tolerated (0.15); PolyPhen benign (0.01); called by muse, varscan2
- AC011005.1 | c.600C>T p.L200= | Silent (SNP) | VAF 30/679 reads (4%) | catalogued as rs1012320898; called by muse, mutect2
- COX4I1 | c.135C>T p.P45= | Silent (SNP) | VAF 71/327 reads (22%) | catalogued as rs1275049598; called by muse, mutect2, varscan2
- ITGA7 | c.321C>T p.D107= | Silent (SNP) | VAF 54/532 reads (10%) | called by muse, mutect2, varscan2
- KAT14 | c.306T>C p.F102= | Silent (SNP) | VAF 91/267 reads (34%) | catalogued as COSV100890109; called by muse, mutect2, varscan2
- KIAA1210 | c.4086G>A p.E1362= | Silent (SNP) | VAF 34/635 reads (5%) | called by muse, mutect2
- MB21D2 | c.1398G>A p.P466= | Silent (SNP) | VAF 33/401 reads (8%) | catalogued as rs774984184; called by muse, mutect2
- MYOCD | c.1191C>T p.L397= | Silent (SNP) | VAF 25/212 reads (12%) | called by muse, mutect2, varscan2
- PDE4D | c.207A>G p.Q69= | Silent (SNP) | VAF 16/182 reads (9%) | catalogued as rs1158333216; called by muse, mutect2
- PRKCA | c.63C>T p.A21= | Silent (SNP) | VAF 38/365 reads (10%) | called by muse, mutect2, varscan2
- PRSS23 | c.288C>T p.R96= | Silent (SNP) | VAF 25/430 reads (6%) | called by muse, mutect2
- SYNPO | c.2571G>T p.L857= (on ENST00000394243 / NM_001166208.2; = p.L613= on NM_007286.6) | Silent (SNP) | VAF 222/860 reads (26%) | catalogued as COSV100302330; called by muse, mutect2, varscan2
- TMF1 | c.1143T>C p.N381= | Silent (SNP) | VAF 18/109 reads (17%) | catalogued as COSV101275478; called by muse, mutect2, varscan2
- USH2A | c.6066G>A p.L2022= | Silent (SNP) | VAF 28/541 reads (5%) | called by muse, mutect2
- ABCC9 | c.406+385C>T | Intron (SNP) | VAF 15/74 reads (20%) | called by muse, mutect2, varscan2
- AL353804.7 | chrX:73846299 C>A | 5'Flank (SNP) | VAF 84/262 reads (32%) | called by muse, mutect2, varscan2
- CATSPER2 | c.561+50T>A | Intron (SNP) | VAF 16/131 reads (12%) | called by mutect2, varscan2
- DENND10P1 | n.1026G>C | RNA (SNP) | VAF 25/559 reads (4%) | called by muse, mutect2
- DENND10P1 | n.1092G>C | RNA (SNP) | VAF 27/399 reads (7%) | called by muse, mutect2
- FRMD7 | c.-8C>G | 5'UTR (SNP) | VAF 66/474 reads (14%) | called by muse, mutect2, varscan2
- KDM2A | c.2769-135_2769-134dup | Intron (INS) | VAF 14/63 reads (22%) | called by mutect2, pindel, varscan2
- MLF1 | c.-12_1del | 5'UTR (DEL) | VAF 20/131 reads (15%) | called by mutect2, pindel, varscan2
- MROH6 | c.1867+18C>G | Intron (SNP) | VAF 11/63 reads (17%) | called by muse, mutect2
- NPHP4 | c.3316-126C>T | Intron (SNP) | VAF 93/266 reads (35%) | catalogued as rs773690537; called by muse, mutect2, varscan2
- RAD23B | c.*1996A>T | 3'UTR (SNP) | VAF 28/322 reads (9%) | called by muse, mutect2
- STXBP3 | c.-52A>G | 5'UTR (SNP) | VAF 14/218 reads (6%) | catalogued as rs967235175; called by muse, mutect2
- TMTC1 | c.1532+3136G>T | Intron (SNP) | VAF 26/242 reads (11%) | called by muse, mutect2, varscan2
